Gene-level copy-number profile of tumor specimen TCGA-61-2008-01A from TCGA case TCGA-61-2008, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIC; Tumor grade: G2; Age at diagnosis: 40.5 years (14,791 days).
Specimen TCGA-61-2008-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.715a71ed-ca25-4124-8273-0bf88e69d5cb.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-61-2008-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9253c97c-8f7e-4ea1-89d2-4cc3f388376b

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2,151; copy number 2: 18,542; copy number 3: 19,731; copy number 4: 13,801; copy number 5: 4,052; copy number 6: 459; copy number 7: 678; copy number 8: 398.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-61-2008-01A-02D-0663-01): tumor purity 0.78, ploidy 3.13, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,076 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:53,283,429–53,347,586, 1 gene, copy number 7 (within-gene range 5–7): DCP1A.
- chr3:53,328,963–58,537,283, 80 genes, copy number 7 (broad region; genes not listed).
- chr3:172,425,850–198,222,513, 522 genes, copy number 7 (broad region; genes not listed).
- chr8:119,350,291–145,066,685, 473 genes, copy number 7–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,796. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
